Somatic mutation profile of tumor specimen TCGA-IE-A4EI-01A (aliquot TCGA-IE-A4EI-01A-11D-A24N-09) from TCGA case TCGA-IE-A4EI, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 67.5 years (24,663 days).
Specimen TCGA-IE-A4EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56652031-2416-4d93-a98a-81ed81e49ce9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A4EI-10A (Blood Derived Normal), aliquot TCGA-IE-A4EI-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bdc27d2-0786-4553-933c-40e2f661be8e

The open-access MAF lists 34 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Frame Shift Del 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD4 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs796646805, COSV53530461; called by muse, mutect2, varscan2
- FLCN | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1327627870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDPD4 | c.1253C>A p.A418E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as COSV60019370; called by muse, mutect2
- ITPKA | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53026758; called by muse, mutect2, varscan2
- SKIV2L | c.3533G>T p.R1178L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV100514873; called by muse, mutect2, varscan2
- STAT5A | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs1406350203, COSV61805851; called by muse, mutect2, varscan2
- STOML2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99956965; called by muse, mutect2, varscan2
- BCL2L14 | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.649); called by muse, mutect2
- BOD1L1 | c.4243G>A p.D1415N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRIM1 | c.2003_2004insAT p.Q669Cfs*114 | Frame Shift Ins (INS) | VAF 56/64 reads (88%) | called by mutect2, varscan2
- EFCAB7 | c.1726A>T p.I576F | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- GATA2 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- HERC2 | c.2522A>C p.H841P | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- HNF1B | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HUWE1 | c.10688G>C p.G3563A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS6L | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNV1 | c.1124C>A p.T375N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MAGEC3 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RIC1 | c.584del p.V195Efs*62 | Frame Shift Del (DEL) | VAF 12/21 reads (57%) | called by mutect2, pindel, varscan2
- SLC2A2 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SRGAP1 | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- STOM | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TBC1D8B | c.219A>T p.Q73H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TP53 | c.1007_1008del p.E336Afs*10 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, pindel, varscan2
- BAK1 | c.54C>A p.A18= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CACNA1S | c.5562C>T p.S1854= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- FAM120A | c.2412G>A p.G804= | Silent (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- GBX2 | c.717C>T p.G239= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.2145G>C p.L715= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV51722007; called by muse, mutect2, varscan2
- MYH14 | c.5967C>A p.S1989= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- OR2B3 | c.486G>A p.L162= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101013831; called by muse, mutect2
- RIMBP3 | c.2694G>T p.P898= | Silent (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- SLC27A4 | c.367C>T p.L123= | Silent (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- BX119917.1 | n.46G>C | RNA (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
